Somatic mutation profile of tumor specimen TCGA-AS-3778-01A (aliquot TCGA-AS-3778-01A-01W-0886-08) from TCGA case TCGA-AS-3778, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 35.4 years (12,937 days).
Specimen TCGA-AS-3778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e11d9441-e137-46b3-964b-7cd62c429f63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AS-3778-10A (Blood Derived Normal), aliquot TCGA-AS-3778-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e36287d5-7b0f-45de-b824-e565e578265f

The open-access MAF lists 88 somatic variants for this specimen: 68 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 19, Frame Shift Ins 9, Frame Shift Del 7, Nonsense Mutation 4, Splice Site 3, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.029); catalogued as rs139429793; ClinVar: pathogenic; called by muse, varscan2
- SMC3 | c.2005T>G p.Y669D | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs776056911, COSV100700079, COSV62421623; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AL592490.1 | c.2385C>A p.F795L | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69427327, COSV69427462; called by muse, mutect2
- CASP14 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 69/226 reads (31%) | catalogued as COSV55666249; called by muse, mutect2, varscan2
- CSMD3 | c.148G>T p.V50F | Missense Mutation (SNP) | VAF 127/239 reads (53%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.142); catalogued as COSV52133464, COSV52155381, COSV52272117; called by muse, mutect2, varscan2
- CYTH2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.774); catalogued as rs1804728, COSV57310342; called by muse, mutect2, varscan2
- DCP2 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 19/590 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV66616665, COSV66617978; called by muse, mutect2
- DPY19L1 | c.1457T>C p.I486T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV60583586; called by muse, mutect2, varscan2
- DST | c.18236G>T p.G6079V (on ENST00000361203 / NM_001374722.1; = p.G3776V on NM_015548.5) | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55032392; called by muse, mutect2
- DYNC1H1 | c.4074+1G>A p.X1358_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | catalogued as COSV64140457, COSV64143860; called by muse, mutect2, varscan2
- ERP27 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as COSV56764350; called by muse, mutect2
- FAM3D | c.416dup p.A140Cfs*18 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | catalogued as rs762012279; called by pindel, varscan2
- FAT3 | c.6628G>T p.A2210S | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53155465; called by muse, mutect2
- GCOM1 | c.332T>C p.L111S | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51095151; called by muse, varscan2
- KCNC1 | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56397085; called by muse, mutect2, varscan2
- KIF3B | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 91/179 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV65228873; called by muse, mutect2, varscan2
- KRT4 | c.425A>G p.K142R | Missense Mutation (SNP) | VAF 188/545 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV53409030; called by muse, mutect2, varscan2
- MANBA | c.2041G>A p.E681K (on ENST00000642252; = p.E635K on NM_005908.4) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56968942; called by muse, mutect2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 13/59 reads (22%) | catalogued as rs777328830; called by mutect2, varscan2
- MFAP3L | c.1132G>T p.V378L | Missense Mutation (SNP) | VAF 56/694 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV64372749; called by muse, mutect2
- MUC16 | c.22433C>T p.A7478V | Missense Mutation (SNP) | VAF 18/600 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.148); catalogued as COSV67483287; called by muse, mutect2
- NCOR2 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1231185993, COSV62302037; called by muse, mutect2, varscan2
- NLRP7 | c.1737G>T p.Q579H | Missense Mutation (SNP) | VAF 87/712 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60179331, COSV60182925; called by muse, mutect2, varscan2
- NSUN5 | c.674del p.P225Rfs*24 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | catalogued as rs782731794; called by mutect2, pindel
- OR5AP2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs747083094, COSV57258369; called by muse, mutect2, varscan2
- PCDHB7 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV50801583; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 20/172 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- PKHD1 | c.646C>A p.H216N | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61889803; called by muse, mutect2, varscan2
- POLE | c.4461C>G p.I1487M | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV57687029; called by muse, mutect2, varscan2
- PPP1R15B | c.1620A>T p.E540D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.306); catalogued as COSV65816341; called by muse, mutect2, varscan2
- RAET1G | c.498A>T p.R166S | Missense Mutation (SNP) | VAF 106/422 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV66274843; called by muse, mutect2, varscan2
- RASGRP2 | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV62450503; called by muse, mutect2, varscan2
- RPS29 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs368998907; called by muse, mutect2, varscan2
- RPUSD2 | c.1195G>C p.G399R | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59766144; called by muse, mutect2, varscan2
- RUSC1 | c.2576G>T p.R859I (on ENST00000368352 / NM_001105203.2; = p.R390I on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/698 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV52741780; called by muse, mutect2
- RXFP3 | c.1374dup p.R459Afs*37 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | catalogued as rs756773263; called by pindel, varscan2
- SARS1 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 92/848 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.236); catalogued as COSV52322624; called by muse, mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs746556543; called by mutect2, varscan2
- SLC1A4 | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV52235574; called by muse, mutect2
- SLC26A11 | c.342C>G p.F114L | Missense Mutation (SNP) | VAF 225/443 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0.113); catalogued as COSV58340117; called by muse, mutect2, varscan2
- SLC7A10 | c.913-1G>C p.X305_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53506529; called by muse, mutect2
- TBX18 | c.1200C>A p.F400L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV63737679; called by muse, mutect2
- THRAP3 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.382); catalogued as COSV63569251; called by muse, mutect2, varscan2
- TLN2 | c.3598A>G p.N1200D | Missense Mutation (SNP) | VAF 278/485 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as COSV60893664; called by muse, mutect2, varscan2
- USP26 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs891270763, COSV63708271, COSV63708389, COSV63709428; called by muse, mutect2
- UTP18 | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56584794; called by muse, mutect2, varscan2
- XPC | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV53207061; called by muse, mutect2, varscan2
- XPOT | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 30/486 reads (6%) | catalogued as COSV60347296; called by muse, mutect2
- ZBTB41 | c.1037A>G p.E346G | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV66359760; called by muse, mutect2, varscan2
- ZMYM4 | c.992C>A p.S331* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV58915141; called by muse, mutect2
- ZMYM4 | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV58915152; called by muse, mutect2
- ADGRF4 | c.325del p.S109Lfs*2 | Frame Shift Del (DEL) | VAF 258/523 reads (49%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.300del p.H100Qfs*7 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- BCHE | c.907_913del p.N303Hfs*12 | Frame Shift Del (DEL) | VAF 41/158 reads (26%) | called by mutect2, pindel, varscan2
- BTBD1 | c.1146_1182del p.I382Mfs*22 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by pindel, varscan2*
- CDC42BPB | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLTC | c.912dup p.V305Cfs*6 | Frame Shift Ins (INS) | VAF 183/384 reads (48%) | called by mutect2, pindel, varscan2
- DENND4C | c.4335C>G p.D1445E (on ENST00000434457 / NM_001330640.2; = p.D1396E on NM_017925.7) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.149); called by mutect2, varscan2
- KPNA4 | c.508del p.H170Ifs*16 | Frame Shift Del (DEL) | VAF 45/104 reads (43%) | called by mutect2, pindel, varscan2
- L3HYPDH | c.1015_1019dup p.I341Lfs*2 | Frame Shift Ins (INS) | VAF 9/72 reads (13%) | called by mutect2, pindel
- LRRC32 | c.1281dup p.P428Afs*3 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by pindel, varscan2
- LTB | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- NYNRIN | c.4750_4755del p.R1584_S1585del | In Frame Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- PKN3 | c.2598_2599insTGGGTCTAAGCCCCACTCAGTCCCTTTGAT p.S866_L867insWV* | Nonsense Mutation (INS) | VAF 69/110 reads (63%) | called by mutect2, varscan2*
- RSPO1 | c.437-1G>T p.X146_splice | Splice Site (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- SRCIN1 | c.2680T>G p.F894V (on ENST00000621492; = p.F860V on NM_025248.3) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- STAG1 | c.1910_1911del p.S637Kfs*4 | Frame Shift Del (DEL) | VAF 29/141 reads (21%) | called by mutect2, pindel, varscan2
- VHL | c.413dup p.S139Ifs*5 | Frame Shift Ins (INS) | VAF 61/206 reads (30%) | called by mutect2, pindel, varscan2
- ADRA2A | c.273C>T p.A91= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- C1orf141 | c.864G>A p.A288= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as rs139606703; called by mutect2, varscan2
- CHRNE | c.789C>T p.F263= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV53419390; called by muse, mutect2, varscan2
- CTNNA2 | c.970C>A p.R324= | Silent (SNP) | VAF 56/195 reads (29%) | catalogued as COSV63589936, COSV63602878; called by muse, mutect2, varscan2
- CTR9 | c.2877G>A p.K959= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV63729332; called by muse, mutect2, varscan2
- EHD3 | c.990G>A p.E330= | Silent (SNP) | VAF 231/333 reads (69%) | catalogued as COSV59032369; called by muse, mutect2, varscan2
- GRK4 | c.1344G>T p.V448= (on ENST00000398052 / NM_182982.3; = p.V416= on NM_005307.3) | Silent (SNP) | VAF 122/652 reads (19%) | catalogued as COSV61670517; called by muse, mutect2, varscan2
- GUCY2D | c.1131T>A p.A377= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV54697932; called by muse, mutect2, varscan2
- KRT31 | c.96C>T p.P32= | Silent (SNP) | VAF 14/362 reads (4%) | catalogued as rs929441381, COSV52434964, COSV52437255; called by muse, mutect2
- KRT76 | c.1916G>A p.*639= | Silent (SNP) | VAF 59/397 reads (15%) | catalogued as COSV60121513; called by muse, mutect2, varscan2
- MIOS | c.2331C>T p.G777= | Silent (SNP) | VAF 68/283 reads (24%) | catalogued as COSV60770018; called by muse, mutect2, varscan2
- NLRP4 | c.669G>A p.P223= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs746075034, COSV56707602, COSV56708334; called by muse, mutect2, varscan2
- NOS1 | c.2937G>A p.V979= | Silent (SNP) | VAF 68/623 reads (11%) | catalogued as COSV57618559; called by muse, mutect2, varscan2
- PEX7 | c.459C>A p.G153= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV59251175; called by muse, mutect2
- PHLPP2 | c.3915T>C p.P1305= | Silent (SNP) | VAF 66/177 reads (37%) | catalogued as COSV62426582; called by muse, mutect2, varscan2
- RYR1 | c.12462G>A p.P4154= | Silent (SNP) | VAF 238/771 reads (31%) | catalogued as rs752478710, COSV62106282; called by muse, mutect2, varscan2
- SLC25A33 | c.94C>T p.L32= | Silent (SNP) | VAF 106/800 reads (13%) | catalogued as COSV57021413; called by muse, mutect2, varscan2
- UGT1A10 | c.174C>T p.V58= | Silent (SNP) | VAF 14/328 reads (4%) | catalogued as rs1453192033, COSV60837507; called by muse, mutect2
- UNC5C | c.2226C>A p.R742= | Silent (SNP) | VAF 42/257 reads (16%) | catalogued as COSV71661455; called by muse, mutect2, varscan2
- SNORD115-19 | n.54_64del | RNA (DEL) | VAF 30/210 reads (14%) | called by pindel, varscan2
